Somatic mutation profile of tumor specimen MP2PRT-PATCGP-TMP1-A (aliquot MP2PRT-PATCGP-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATCGP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (2,984 days).
Specimen MP2PRT-PATCGP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 547f842c-5d01-4d7a-aaa6-d383c86aecad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCGP-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCGP-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ffd6af3-5dfd-4c8f-9d35-30d94200cfee

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 100/422 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- ARHGAP36 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 58/786 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs747749800, COSV99358079; called by muse, mutect2
- COL5A3 | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs772890229; called by muse, mutect2, varscan2
- COL6A2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775751831, COSV56008562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX24 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 151/695 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as rs748177362, COSV104400665; called by muse, mutect2, varscan2
- HLA-F | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99466054, COSV99466162; called by muse, mutect2, varscan2
- KDM6A | c.2453C>G p.S818* | Nonsense Mutation (SNP) | VAF 123/527 reads (23%) | catalogued as COSV65039345; called by muse, mutect2, varscan2
- KRTAP13-4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 95/740 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs147969446, COSV61878992; called by muse, mutect2, varscan2
- PLEKHG6 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs776513105, COSV99164199; called by muse, mutect2, varscan2
- POLQ | c.3656C>A p.P1219H | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs1219736469; called by muse, mutect2, varscan2
- RIMBP2 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs760979945; called by muse, mutect2
- SPAAR | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 95/421 reads (23%) | PolyPhen benign (0.196); catalogued as rs773879962; called by muse, mutect2, varscan2
- SYNJ1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 62/540 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100449040; called by muse, mutect2, varscan2
- HDAC8 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8B2 | c.919A>T p.I307F | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCSD1 | c.72dup p.G25Rfs*4 | Frame Shift Ins (INS) | VAF 93/498 reads (19%) | called by mutect2, pindel, varscan2
- ERBB3 | c.2967G>A p.G989= | Silent (SNP) | VAF 68/382 reads (18%) | catalogued as rs1369471785; called by muse, mutect2, varscan2
- H1-6 | c.195G>T p.A65= | Silent (SNP) | VAF 52/612 reads (8%) | catalogued as rs774642735; called by muse, mutect2
- LOXHD1 | c.4734C>T p.Y1578= | Silent (SNP) | VAF 42/450 reads (9%) | catalogued as rs376338995; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- NACC2 | c.225C>T p.P75= | Silent (SNP) | VAF 172/746 reads (23%) | catalogued as rs1310252405; called by muse, mutect2, varscan2
- NECTIN4 | c.348C>T p.N116= | Silent (SNP) | VAF 146/730 reads (20%) | catalogued as rs762500186, COSV63512951; called by muse, mutect2, varscan2
- OR7E24 | c.132C>A p.V44= | Silent (SNP) | VAF 41/476 reads (9%) | catalogued as COSV101509691, COSV71702263; called by muse, mutect2
- SLC25A31 | c.225C>T p.R75= | Silent (SNP) | VAF 70/341 reads (21%) | catalogued as rs1464774325, COSV55422469; called by muse, mutect2, varscan2
